Surgical pathology report (de-identified scan), TCGA case TCGA-IQ-A61E, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-IQ-A61E-01A (Primary Tumor).

[page 1 of 11]
RUN DATE:
RUN TIME:

*** FINAL REPORT ***

PAGE 1

Received:
Copies to:

Collected:

SPECIMEN ID:

- A. NECK, NOS - Right neck dissection levels 2A,3,4,
- B. NECK, NOS - Right level 1B neck dissection, C. NECK, NOS - Right neck level 2B,
- D. NECK, NOS - Left neck level 1A,1B, E. SOFT TISSUE - Right tail of carotid,
- F. NECK, NOS - Left neck levels 2A,3,4, G. NECK, NOS - Left neck level 2B,
- H. TOOTH - Teeth #29,30,31,
- I. TONGUE - Right subtotal glossectomy with right marginal mandibulectomy,
- J. MOUTH - Right retromolar trigone margin - Frozen section,
- K. MOUTH - Medial retromolar margin - Frozen section,
- L. MOUTH - Inferior soft palate - Frozen section,
- M. MOUTH - Right floor of the mouth margin - Frozen section,
- N. MOUTH - Midline floor of the mouth margin - Frozen section,
- O. MOUTH - Left floor of the mouth margin - Frozen section,
- P. MOUTH - Right lateral pharyngeal wall margin - Frozen section,
- Q. MOUTH - Right vallecula mucosa margin - Frozen section,
- R. TONGUE - Left base of tongue - Frozen section,
- S. TONGUE - Left posterior tongue dorsal margin - Frozen section,
- T. NECK, NOS - Suprahyoid muscle margin - Frozen section,
- U. TONGUE - Left base of tongue deep muscle margin - Frozen section,
- V. NERVE - Proximal right hypoglossal nerve margin - Frozen section,
- W. MOUTH - Deep left floor of mouth margin - Frozen section,
- X. TONGUE - Left ventral tongue deep margin, clip inferior - Frozen section,
- Y. TONGUE - Left dorsal tongue margin, clip anterior - Frozen section,
- Z. TONGUE - Left deep posterior tongue muscle margin - Frozen section,
- AA. MOUTH - Deep left middle deep muscle margin - Frozen section,
- BB. TONGUE - Left anterior tongue deep muscle margin - Frozen section,
- CC. NECK, NOS - Right proximal digastric margin - Frozen section

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

ICD-O-3

Carcinoma, squamous cell NOS
8670/3

Site Tongue NOS C02.9

JW 5/14/13

[page 2 of 11]
(Continued)

A. RIGHT NECK DISSECTION LEVELS 2A,3,4:

Fifteen lymph nodes, negative for malignancy (0/15).

B. RIGHT LEVEL 1B NECK DISSECTION:

Salivary gland, no specific pathologic change.

One lymph node, negative for malignancy (0/1).

C. RIGHT NECK LEVEL 2B:

Salivary gland, no specific pathologic change.

Eight lymph nodes, negative for malignancy (0/8).

D. LEFT NECK LEVEL 1A AND 1B:

Salivary gland, no specific pathologic change.

Five lymph nodes, negative for malignancy (0/5).

E. RIGHT TAIL OF CAROTID:

Salivary gland, nerve, and connective tissue, no specific pathologic change.

F. LEFT NECK LEVELS 2A,3,4:

Ten lymph nodes, negative for malignancy (0/10).

G. LEFT NECK LEVEL 2B:

Five lymph nodes, negative for malignancy (0/5).

H. TEETH #29, 30, 31:

Teeth, gross only.

I. RIGHT SUBTOTAL GLOSSECTOMY WITH RIGHT MARGINAL MANDIBULECTOMY:

INVASIVE, MODERATELY TO POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 6 cm in

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 3 of 11]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

greatest dimension.

Perineural invasion is present.

No lymphovascular invasion seen.

Specimen margins are negative for tumor.

See Tumor Summary.

AJCC: pT3, pN0, pMX

J. RIGHT RETROMOLAR TRIGONE MARGIN:

Squamous mucosa, negative for malignancy.

K. MEDIAL RETROMOLAR MARGIN:

Squamous mucosa, negative for malignancy.

L. INFERIOR SOFT PALATE:

Squamous mucosa, negative for malignancy.

M. RIGHT FLOOR OF MOUTH MARGIN:

Squamous mucosa, negative for malignancy.

N. MIDLINE FLOOR OF MOUTH MARGIN:

Squamous and respiratory-type mucosa, negative for malignancy.

O. RIGHT VALLECULAR MUCOSA MARGIN:

Squamous and respiratory-type mucosa, negative for malignancy.

P. RIGHT LATERAL PHARYNGEAL WALL MARGIN:

Squamous mucosa with underlying lymphoid tissue, negative for malignancy.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 4 of 11]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Q. RIGHT VALLECULA MUCOSA MARGIN:

Squamous mucosa with underlying lymphoid tissue, negative for malignancy.

R. LEFT BASE OF TONGUE:

Squamous mucosa with underlying lymphoid tissue, negative for malignancy.

S. LEFT POSTERIOR TONGUE DORSAL MARGIN:

Squamous mucosa with underlying lymphoid tissue, negative for malignancy.

T. SUPRAHYOID MUSCLE MARGIN:

Skeletal muscle, negative for malignancy.

U. LEFT BASE OF TONGUE DEEP MUSCLE MARGIN:

Skeletal muscle, negative for malignancy.

V. PROXIMAL RIGHT HYPOGLOSSAL NERVE MARGIN:

Peripheral nerve, negative for malignancy.

W. DEEP LEFT FLOOR OF MOUTH MARGIN:

Skeletal muscle, negative for malignancy.

X. LEFT VENTRAL TONGUE DEEP MARGIN:

Squamous mucosa, negative for malignancy.

Y. LEFT DORSAL TONGUE MARGIN:

Squamous mucosa, negative for malignancy.

Z. LEFT DEEP POSTERIOR TONGUE MUSCLE MARGIN:

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 5 of 11]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Skeletal muscle, negative for malignancy.

AA. DEEP LEFT MIDDLE DEEP MUSCLE MARGIN:

Skeletal muscle, negative for malignancy.

BB. LEFT ANTERIOR TONGUE DEEP MUSCLE MARGIN:

Skeletal muscle, negative for malignancy.

CC. RIGHT PROXIMAL DIGASTRIC MARGIN:

Dense connective tissue and skeletal muscle, negative.

Pathology Cancer Case Summary

Specimen:

Ventral surface of tongue, not otherwise specified (NOS)

Mandible

Received: In formalin

Procedure:

Resection:

Glossectomy (subtotal)

Mandibulectomy (marginal)

Specimen Integrity: Intact

Specimen Size:

Tongue: 7 x 4.5 x 3 cm

Floor of mouth: 7.5 x 6 x 2 cm

Mandibular bone: 3 x 1.2 x 1 cm

Specimen Laterality: Not specified

Tumor Site:

Lateral border of tongue

Ventral surface of tongue, NOS

Dorsal surface of tongue, NOS

Anterior two-thirds of tongue, NOS

Tumor Focality: Single focus

Tumor Size:

Greatest dimension: 6 cm

Additional dimensions: 4 x 3 cm

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 6 of 11]
(Continued)

*** FINAL DIAGNOSIS *** (Continued)

Tumor Description:

Endophytic

Ulcerated

Histologic Type: Squamous cell carcinoma, conventional

Histologic Grade:

G2: Moderately differentiated to poorly differentiated

Margins:

Margins Uninvolved by invasive carcinoma

Distance from closest margin: 1 mm or 0.1 cm

Specify margin: Soft tissue specimen margin

Treatment Effect: Not identified

Lymph-Vascular Invasion: Not identified

Perineural Invasion: Present

Lymph Nodes, Extranodal Extension: Not identified

Pathologic Staging (pTNM):

Primary Tumor (pT):

pT3: Tumor more than 4 cm in greatest dimension

Regional Lymph Nodes (pN):

pN0: No regional lymph node metastasis

Number of Lymph Nodes Examined: 44

Number of Lymph Nodes Involved: 0

Distant Metastasis (pM):

Not applicable

AJCC: pT3, pN0, pMx

CLINICAL HISTORY-

PRE-OP DX: Not Provided

PROCEDURE: Not provided

RELEVANT CLINICAL HX: History of SCC (R) Tongue

GROSS DESCRIPTION:

- A. Received in formalin and labeled "Right neck dissection levels 2, 3, 4" are two fibroadipose tissue fragments measuring 9.5 x 3.5 x 1.0 and 4.0 x 3.0 x 0.6 cm. Eleven possible lymph nodes are identified, ranging from 2.0 to 0.3 cm in largest in

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 7 of 11]
(Continued)

GROSS DESCRIPTION: (Continued)

diameter. Specimen submitted as follows:

Cassettes #1&2: The same lymph node bisected
Cassette #3: Two possible lymph nodes in toto
Cassette #4: Three possible lymph nodes in toto
Cassette #5: Four possible lymph nodes in toto
Cassette #6: One possible lymph node in toto

- B. Received in formalin and labeled "Right level 1B neck dissection" and is a 4.8 x 3.5 x 2.0 cm, yellow-tan tissue fragment. Specimen is composed of a salivary gland (3.0 x 2.2 x 1.5 cm) and attached fibroadipose tissue. Three possible lymph nodes are identified, ranging from 0.8 to 1.2 cm in largest diameter. The cut surface of salivary gland is yellow-tan and lobulated. No lesions are grossly present. Specimen submitted as follows:

Cassette #1: Three possible lymph nodes in toto
Cassette #2: Representative section of the salivary gland.

- C. Received in formalin and labeled "Right neck level 2B" is a 3.0 x 2.8 x 1.5 cm fibroadipose tissue. The specimen most likely represents a matted lymph node. The specimen is bisected and submitted in toto in two cassettes.

- D. Received in formalin and labeled "Left neck levels 1A and 1B" is an 8.0 x 3.0 x 2.5 cm fibroadipose tissue fragment. Specimen is composed of a salivary gland (4.0 x 2.8 x 1.5 cm) and attached fibroadipose tissue. No masses or lesions are grossly present in the salivary gland parenchyma. Five possible lymph nodes are identified, ranging from 0.2 to 1.3 cm in largest diameter. Specimen submitted as follows:

Cassette #1: Two possible lymph nodes in toto
Cassette #2: Three possible lymph nodes in toto
Cassette #3: Representative section of the salivary gland

- E. Received in formalin and labeled "Right tail of the Carotid" is a 1.2 x 0.8 x 0.4 cm, pale tan tissue fragment. Specimen is bisected and submitted in toto in one cassette.

- F. Received in formalin and labeled "Left neck levels 2A,3,4" is a 9.0 x 4.5 x 1.0 cm fibroadipose tissue fragment. Nine possible lymph nodes are identified, ranging from 1.8 to 0.3 cm in largest diameter. Specimen submitted as follows:

Cassette #1: One possible lymph node, bisected
Cassette #2: One possible lymph node, bisected

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call and
return the report to us by mail.

[page 8 of 11]
(Continued)

GROSS DESCRIPTION: (Continued)

Cassette #3: Three possible lymph nodes in toto

Cassette #4: Four possible lymph nodes in toto

- G. Received in formalin and labeled as "Left neck level 2B" is a 3.8 x 3.0 x 1.0 cm fibroadipose tissue fragment. Five possible lymph nodes are identified, ranging from 0.8 to 0.2 cm in largest diameter. Specimen submitted as follows:

Cassette #1: Five possible lymph nodes in toto

- H. Received in formalin and labeled "Teeth #'s 29,30,31" are three teeth ranging from 2.0 cm to 1.5 cm in largest diameter. In the same container, there is also a bone or tooth fragment measuring 0.6 x 0.3 x 0.2 cm. For gross description only.

- I. Received in formalin labeled "Right subtotal glossectomy with right marginal mandibulectomy" is a composite resection including tongue (7.0 x 4.5 x 3.0 cm), floor of mouth (7.5 x 6.0 x 2.0 cm), and fragment of mandibular bone (3.0 x 1.2 x 1.0 cm). The specimen is tagged with a double stitch at the anterior aspect. The mucosa (medial margin) is inked red, and soft tissue margin is inked black. There is an ulcerated, ill-defined, white infiltrating lesion, occupying approximately 80% of the specimen and extending grossly to the soft tissue margin, and measuring 6.0 x 4.0 x 3.0 cm. It does not reach the mandibular bone grossly. Sections are submitted as follows:

Cassette #1: The tumor with relationship to the margins
Cassettes #2-6: Composite section of the tumor
Cassette #7: Another representative section of the tumor
Cassette #8: Tumor with relationship to possible lymph node
Cassette #9: The bone margin
Cassette #10: Representative section of bone

- J. Received fresh labeled "Right retromolar margin" is a 1.2 x 0.5 x 0.2 cm, pale-tan tissue fragment. Specimen submitted toto in one cassette for frozen section.
- K. Received fresh labeled "Medial retromolar margin" is a 0.8 x 0.5 x 0.3 cm yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- L. Received fresh labeled "Inferior soft palate" is a 0.7 x 0.5 x 0.2 cm, yellow-tan fragment. Specimen submitted in toto in one cassette for frozen section.
- M. Received fresh labeled "Right floor of mouth margin" is a 1.3 x 0.4 x 0.3 cm, yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 9 of 11]
(Continued)

GROSS DESCRIPTION: (Continued)
section.

- N. Received fresh labeled "Midline floor of mouth margin" is a 1.4 x 0.4 x 0.3 cm, yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- O. Received fresh labeled "Left floor of mouth margin" is a 1.4 x 0.3 x 0.3 cm, yellow-tan tissue fragment. Specimen submitted toto in one cassette for frozen section.
- P. Received fresh labeled "Right lateral pharyngeal wall margin" is a 1.9 x 0.2 x 0.2 cm, yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- Q. Received fresh labeled "Right vallecula mucosal margin" is a 1.4 x 0.2 x 0.2 cm, yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- R. Received fresh labeled "Left base of tongue" is a 1.7 x 0.3 x 0.2 cm, yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- S. Received fresh labeled "Left posterior tongue dorsal margin" is a 1.9 x 0.2 x 0.2 cm, yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- T. Received fresh labeled "Suprahyoid muscle margin" is a 2.7 x 0.4 x 0.3 cm, brown soft tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- U. Received fresh labeled "Left Base of tongue deep muscle margin" is a 1.0 x 0.7 x 0.2 cm, yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- V. Received fresh labeled "Proximal right Hypoglossal nerve margin" is a 0.4 x 0.2 x 0.2 cm, yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- W. Received fresh labeled "Left deep floor of mouth margin" is a 1.4 x 1.1 x 0.3 cm, yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- X. Received fresh labeled "Left ventral tongue margin" is a 1.0 x 0.6 x 0.2 cm,

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 10 of 11]
(Continued)

GROSS DESCRIPTION: (Continued)

yellow-tan tissue fragment. The margin surrounding the clip is inked black. Specimen submitted in toto in one cassette for frozen section.

- Y. Received fresh labeled "Left dorsal tongue margin" is a 4.3 x 0.3 x 0.2 cm, yellow-tan tissue fragment. The area surrounding the clip is inked black. Specimen submitted in toto in one cassette for frozen section.
- Z. Received fresh labeled "Left deep posterior tongue muscle" is a 0.5 x 0.4 x 0.3 cm, yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- AA. Received fresh labeled "Left middle deep muscle margin" is a 0.5 x 0.5 x 0.3 cm, yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- BB. Received fresh labeled "Left anterior tongue deep muscle margin" is a 0.5 x 0.3 x 0.3 cm yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.
- CC. Received fresh labeled "Right proximal digastric margin" is a 4.0 x 2.0 x 0.3 cm, yellow-tan tissue fragment. Specimen submitted in toto in one cassette for frozen section.

OPERATING ROOM CONSULT (FS-CYT)

- J Right retromolar trigone margin: Negative for carcinoma.
- K Medial retromolar margin: Negative for carcinoma.
- L Inferior soft palate: Negative for carcinoma.
- M Right floor of the mouth margin: Negative for carcinoma.
- N midline floor of the mouth margin: Negative for carcinoma.
- O Left floor of the mouth margin: Negative for carcinoma.
- P Right lateral pharyngeal wall margin: Negative for carcinoma.
- Q Right vallecula mucosa margin: Negative for carcinoma.
- R Left base of tongue: Negative for carcinoma.
- S Left posterior tongue dorsal margin: Negative for carcinoma.
- T Suprahypoid muscle margin: Negative for carcinoma.
- U left base of tongue deep muscle margin: Negative for carcinoma.
- V Proximal right hypoglossal nerve margin: Negative for carcinoma.
- W Deep left floor of mouth margin: Negative for carcinoma.
- X Left ventral tongue deep margin, clip inferior: Negative for carcinoma.
- Y Left dorsal tongue margin, clip anterior: Negative for carcinoma.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

[page 11 of 11]
(Continued)

OPERATING ROOM CONSULT (FS-CYT): (Continued)

- Z Left deep posterior tongue muscle margin: Negative for carcinoma.
- AA Deep left middle deep muscle margin: Negative for carcinoma.
- BB Left anterior tongue deep muscle margin: Negative for carcinoma.
- CC Right proximal dygastric margin: Negative for carcinoma.

This report is privileged, confidential and exempt from disclosure under applicable law.
If you receive this report inadvertently, please call _____ and
return the report to us by mail.

Source: NCI Genomic Data Commons file 8d329d39-f442-4324-9151-d36bde636974 (TCGA-IQ-A61E.36B74E59-F872-40B8-A074-65E3657D438D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).